Surgical pathology report (de-identified scan), TCGA case TCGA-TT-A6YN, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Pennsylvania, specimen TCGA-TT-A6YN-01A (Primary Tumor).

[page 1 of 2]
Age

Sex: Female

Print Date

Date Collected

Date Received

Accession No.:

Physician

Copy to:

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Clinical Information

year-old female with right pheochromocytoma, complains of headache and palpitations, MRI showing 10.0 x 7.0 cm right adrenal mass.

Pre-Operative Diagnosis: Not specified

Post-Operative Diagnosis: Not specified

Operation: Right adrenalectomy

Specific questions to be answered: None

Specimen:

1 Right Adrenal Gland/Mass

Final Diagnosis

1. Adrenal gland and mass, right, 558.8 grams, adrenalectomy:
Pheochromocytoma, 12.3 cm, right adrenal; tumor confined to adrenal gland. See note.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date.

Note

The PASS score is 4 (diffuse growth; capsule invasion; vascular invasion).

Immunostains with appropriate controls were performed (see Disclaimer) for chromogranin, inhibin, S100, SDHB and Ki67. These showed strong and diffuse positive reaction for chromogranin, negative inhibin and a noncontributory S100. Ki 67 is less than 1%. Stain for SDHB showed strong diffuse positivity in virtually all the tumor cells.

Gross Description

The case is received in one fresh container, labeled with the patient's name and medical record number.

Specimen 1 is designated "right adrenal gland/mass", and consists of an orange-tan, smooth mass weighing 558.8 g, and measuring 12.3 x 9.0 x 9.1 cm. The specimen is entirely inked black. On cut section, the specimen is primarily pink-tan solid with occasional red fluid filled cysts varying in size from 0.5-3.0 cm. The solid component of the mass is friable, and no capsule is identified. A 2.7 x 2.7 x 1.5 cm tan-orange unencapsulated solid nodule is found on cut section.

N/A

Name:

MRN:

[page 2 of 2]
Age.
48 B

Sex: Female

Print Date

Date Collected

Date Received

Accession No.

Physician:

Copy to:

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

The specimen is representatively submitted as follows:

1A -E: nodule

1F-1V: representative sections

SUMMARY OF SECTIONS: 22, multiple, representative

Dictated by:

Microscopic Description

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the Laboratory of Immunohistochemistry, Anatomic Pathology at the [redacted] This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Pathologist(s)

N/A

Name:
MRN:

Source: NCI Genomic Data Commons file 68f6075d-dfef-4fe9-a30c-3eca71b4acfa (TCGA-TT-A6YN.9A17BF09-2EF5-4B5A-A17E-F2058891F451.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).